Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A9OH, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A9OH-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

A. Lymph nodes, right pelvic, dissection: No tumor in 12 lymph node fragments (0/12).

B. Lymph nodes, left pelvic, dissection: No tumor in four lymph nodes (0/4).

C. Prostate gland and seminal vesicle, laparoscopic robot-assisted radical prostatectomy:

- Prostate:

1. Prostatic adenocarcinoma, bilateral, Gleason score 5+3=8, with extracapsular invasion, tumor at inked right bladder margin; see comment.

2. Nodular hyperplasia.

- Seminal vesicles: Right and left seminal vesicles involved by prostatic adenocarcinoma.

COMMENT:

The tumor is a mix of Gleason grades 5, 4, and 3 with predominately pattern 5 present. On slides C8 and C11, tumor is present immediately adjacent to the inked margin (< 0.1 cm) and positive at the right bladder margin (slide C20).

_____ has reviewed slide C4 and concurs with the grade of tumor.

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:**
- Left posterior apex, slide C1.
- Left posterior mid gland, slides C3, 11, 12 and 13.
- Left posterior base, slide C17.
- Left anterior apex, slide C1.
- Left anterior mid gland, slides C3, 14, 15 and 16.

IED 0.3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS 061.9
JP 3/27/14

[page 2 of 3]
-
- Right posterior apex, slide C2.
- Right posterior mid gland, slides C4, 8, 9 and 10.
- Right posterior base, slides C18 and 20.
- Right anterior apex, slide C2.
- Right anterior mid gland, slides C4, 5, 6 and 7.
- **Estimated volume of tumor:** 11.25 cm³.
- **Gleason score:** 5+4, primary pattern 5, secondary pattern 3.
- **Estimated volume > Gleason pattern 3:** 85%.
- **Involvement of capsule:** Tumor invades capsule (slide C4 and C9, right posterior; C13, left posterior; C17, left base; C18, right base).
- **Extraprostatic extension:** Present; slides C4, C9, C13, C17, C18.
- **Margin status for tumor:** Positive; slide C20, right bladder margin.
- **Margin status for benign glands:** No benign glands present at inked excision margins.
- **Involvement of seminal vesicle:** Present, both sides. Tumor is also present in the right vas deferens (slides C18).
- **Perineural infiltration:** Present (slides C3, C9, C11, C17, C18).
- **Prostatic intraepithelial neoplasia (PIN):** None.
- **Lymph node status:** Negative.
- **Total number of lymph nodes examined:** 16.
- **AJCC/UICC stage:** pT3bN0MX.
-

Specimen(s) Received

A:Lymph node, right pelvic

B:Lymph node, left pelvic

C:Prostate and seminal vesicles (fresh)

Clinical History

The patient is a [REDACTED] with prostate cancer who undergoes robot-assisted laparoscopic radical prostatectomy.

Gross Description

The specimen is received in three parts, each labeled with the patient's name and medical record number. Parts A and B are received in formalin.

Part A, labeled "right pelvic lymph node," consists of multiple soft to firm, irregular, pink-tan/yellow fatty tissue fragments measuring 4.4 x 3 x 1 cm in aggregate. Five candidate lymph nodes are found ranging between 0.5 x 0.2 x 0.1 cm through 1.5 x 0.7 x 0.5 cm. The specimen is submitted as follows:

Cassette A1: Four candidate lymph nodes.
Cassette A2: One candidate lymph node.
Cassettes A3-A5: Remaining fatty tissue.

Part B, labeled "left pelvic lymph node," consists of multiple soft to firm, irregular, pink-tan/yellow fatty tissue fragments measuring 2.7 x 1.7 x 0.4 cm in aggregate. Three candidate lymph nodes are found ranging between 0.5 x 0.4 x 0.2 through 1.7 x 0.8 x 0.3 cm. The specimen is submitted as follows:

Cassette B1: Three candidate lymph nodes.
Cassette B2: Remaining fatty tissue.

Part C, received fresh and additionally labeled "prostate and SV," consists of a 49-gram prostate gland with intact seminal vesicles/vas deferens bundles. The gland measures 4.0 cm medial-lateral, 3.5 cm apex-base, and 4.0 cm anterior-posterior. The external surface of the gland is soft, red-tan and is received with a single suture and a single metal clip. The seminal vesicles/vas deferens bundles are soft and red-tan. The left measures 4.5 x 2.5 x 1.0 cm and the right measures 3.5 x 2.0 x 1.0 cm. The right vas deferens measures 3.0 x 0.5 cm and the left measures 2.0 x 0.5 cm. A palpable lesion is noted along the right posterior mid. The right anterior surface of the gland is inked green, the left anterior surface is inked blue, and the posterior surface is inked black. The apical and bladder margins are removed, and the remainder of the gland is serially sectioned from apex to base into five serial

[page 3 of 3]
slices of 5 mm average thickness. The seminal vesicles/vas deferens bundles are attached to serial slice 5. Serial slices reveal a vague, yellow area in the right posterior of slices 1, 2, 3 and 4, and another vague, yellow, irregular area in the left posterior of serial slices 2 and 3. Following further dissection and submission of tissue for pathologic evaluation, tissue is taken from slices 1, 2, 3 and 4 for research purposes. The entire gland is submitted as follows:

Apical margins

Cassettes C1: Left.
Cassettes C2: Right.

Serial slice 1

Cassette C3: Left..
Cassette C4: Right.

Right anterior quadrant

Cassette C5: Serial slice 2.
Cassette C6: Serial slice 3.
Cassette C7: Serial slice 4.

Right posterior quadrant

Cassette C8: Serial slice 2.
Cassette C9: Serial slice 3.
Cassette C10: Serial slice 4.

Left posterior quadrant

Cassette C11: Serial slice 2.
Cassette C12: Serial slice 3.
Cassette C13: Serial slice 4.

Left anterior quadrant

Cassette C14: Serial slice 2.
Cassette C15: Serial slice 3.
Cassette C16: Serial slice 4.

Seminal vesicle bundles

Cassette C17: Left.
Cassette C18: Right.

Bladder margin

Cassette C19: Left.
Cassette C20: Right.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 50b30421-16d4-40b0-abf7-9e85ea3b8c65 (TCGA-V1-A9OH.8B30DB97-6EB7-42EF-8A12-C9B1F1B5251B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).